Somatic mutation profile of tumor specimen TCGA-IA-A83S-01A (aliquot TCGA-IA-A83S-01A-11D-A34Z-10) from TCGA case TCGA-IA-A83S, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 81.3 years (29,677 days).
Specimen TCGA-IA-A83S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b99d9a72-b7cf-4a8a-ad9d-49ea697fc4c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A83S-11A (Solid Tissue Normal), aliquot TCGA-IA-A83S-11A-11D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a7162ab-ae19-487b-9409-87d603f00eb4

The open-access MAF lists 141 somatic variants for this specimen: 113 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 24, Frame Shift Del 14, Nonsense Mutation 5, Frame Shift Ins 4, Splice Site 3, RNA 1, Splice Region 1, 3'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.3082A>G p.I1028V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99425167; called by muse, mutect2, varscan2
- ACE | c.3386T>C p.F1129S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99326300; called by muse, mutect2, varscan2
- ACSM2A | c.1212dup p.G405Rfs*48 (on ENST00000219054; = p.G326Rfs*48 on NM_001308169.2) | Frame Shift Ins (INS) | VAF 17/63 reads (27%) | catalogued as rs755296455; called by mutect2, pindel, varscan2
- ALDH3A2 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV99449525; called by muse, mutect2, varscan2
- ARMH3 | c.947T>G p.L316* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100898746; called by muse, mutect2, varscan2
- ATL2 | c.1106C>G p.P369R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184363, COSV60056491; called by muse, varscan2
- ATP6V0A1 | c.1540T>C p.Y514H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99230386; called by muse, mutect2, varscan2
- ATP7B | c.3626T>C p.L1209P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665977; called by muse, mutect2, varscan2
- C20orf194 | c.1211C>G p.T404S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99330182; called by mutect2, varscan2
- C2orf73 | c.732A>T p.R244S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100471207; called by muse, mutect2, varscan2
- CCDC190 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100905800; called by muse, mutect2, varscan2
- CCDC50 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV101165239; called by muse, mutect2, varscan2
- CDH9 | c.187T>A p.L63M | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99141372; called by muse, mutect2, varscan2
- CENPN | c.714T>G p.I238M | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV100001072, COSV55142228; called by muse, mutect2, varscan2
- CFAP43 | c.3022del p.Q1008Kfs*5 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | catalogued as COSV53376646; called by mutect2, pindel, varscan2
- CIRBP | c.483A>C p.R161S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100309670; called by muse, mutect2, varscan2
- COL5A3 | c.1565C>A p.P522H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1455173095, COSV99318141; called by muse, mutect2, varscan2
- CPT1A | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99680530; called by muse, mutect2, varscan2
- CSE1L | c.723T>A p.N241K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.601); catalogued as COSV99521802; called by muse, mutect2, varscan2
- DAB1 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773619574, COSV100139333; called by muse, mutect2, varscan2
- DAB2IP | c.1458C>T p.Y486= (on ENST00000408936; = p.Y458= on NM_032552.3) | Splice Region (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99404595; called by muse, mutect2, varscan2
- DLEC1 | c.673+2T>A p.X225_splice | Splice Site (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100341359; called by muse, mutect2, varscan2
- DNAH8 | c.12587C>A p.A4196D | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs775837101, COSV100543081; called by muse, mutect2, varscan2
- DNTTIP2 | c.1393T>G p.F465V | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV100785135; called by muse, mutect2, varscan2
- EIF3B | c.1579T>A p.C527S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100703523; called by muse, mutect2, varscan2
- ENTPD8 | c.557A>T p.Y186F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.106); catalogued as COSV100395435; called by muse, mutect2, varscan2
- ERICH1 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV100032164; called by muse, mutect2, varscan2
- ETV5 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112005, COSV60506461; called by muse, mutect2, varscan2
- F10 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as COSV65022554; called by muse, mutect2
- F8 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | catalogued as rs1352296401, CM011329, COSV100811225; called by muse, mutect2, varscan2
- FAM111B | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV100639225; called by muse, mutect2, varscan2
- GABRG2 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as COSV100729474; called by muse, mutect2, varscan2
- GEMIN2 | c.793T>A p.L265M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99158020; called by muse, mutect2, varscan2
- GLG1 | c.3455G>A p.S1152N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV99215217; called by muse, mutect2, varscan2
- GPD1 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993695; called by muse, mutect2, varscan2
- GRHL1 | c.1685A>G p.D562G | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1392272333, COSV100257466; called by muse, mutect2
- GTF2F1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs750319008, COSV66727356; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs1357753418; called by muse, mutect2, varscan2
- IGLV7-46 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs536317077; called by muse, mutect2, varscan2
- ITGAM | c.3110T>A p.F1037Y (on ENST00000648685 / NM_001145808.2; = p.F1036Y on NM_000632.4) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99791700; called by muse, mutect2, varscan2
- LRP1 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV99674170; called by muse, mutect2, varscan2
- LTN1 | c.1425A>C p.K475N | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100797864; called by muse, mutect2, varscan2
- METTL3 | c.1337T>G p.L446R | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99397994; called by muse, mutect2, varscan2
- MUC16 | c.16253A>T p.H5418L | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV101197860; called by muse, mutect2, varscan2
- MUC16 | c.16252C>T p.H5418Y | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV101197862; called by muse, mutect2, varscan2
- MX2 | c.1640A>G p.Q547R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100415704; called by muse, mutect2, varscan2
- NBR1 | c.2559A>T p.R853S | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100357657; called by muse, mutect2, varscan2
- NFE2L1 | c.1495T>C p.S499P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100671334; called by muse, mutect2
- NLRP7 | c.2262C>A p.D754E (on ENST00000340844 / NM_206828.3; = p.D726E on NM_139176.3) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100051528; called by muse, mutect2, varscan2
- NUDT10 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100726778; called by muse, mutect2, varscan2
- NUTM1 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV100148803; called by muse, mutect2
- ODAPH | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100290050; called by muse, mutect2, varscan2
- OR10A2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.981); catalogued as rs1290069002, COSV100224916; called by muse, mutect2, varscan2
- OR4K17 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100210472; called by muse, mutect2, varscan2
- OR5AS1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100546148; called by muse, mutect2, varscan2
- OR5M10 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1565171371, COSV101595858; called by muse, mutect2, varscan2
- PCBP2 | c.30A>C p.L10F | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100827436; called by muse, mutect2, varscan2
- PCF11 | c.1735A>G p.T579A | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100017706; called by muse, mutect2, varscan2
- PDS5A | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100337138; called by muse, mutect2, varscan2
- PFKL | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138177950; called by muse, mutect2, varscan2
- PLEKHH2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56757971; called by muse, mutect2, varscan2
- PPHLN1 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV99871411; called by muse, mutect2, varscan2
- PRDM16 | c.1063C>A p.H355N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99575340; called by muse, mutect2, varscan2
- PRKDC | c.6299T>G p.L2100R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100038197; called by muse, mutect2, varscan2
- PRKRA | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100359396, COSV57868763; called by muse, mutect2, varscan2
- PYCR2 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100661470; called by muse, mutect2, varscan2
- QRFP | c.235A>T p.R79* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100551011; called by muse, mutect2, varscan2
- RAI1 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV99883216, COSV99884631; called by muse, mutect2, varscan2
- RAI1 | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99883220; called by muse, mutect2, varscan2
- RALGAPB | c.2065A>T p.I689F | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV99484653; called by muse, mutect2, varscan2
- RIC8A | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV100254643; called by muse, mutect2, varscan2
- RO60 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV66475300; called by muse, mutect2, varscan2
- RXRA | c.1215G>C p.K405N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100709178, COSV100709316; called by muse, mutect2
- SBF1 | c.1306T>C p.Y436H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62367187; called by muse, mutect2, varscan2
- SEC23IP | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV100956732, COSV100957167; called by muse, mutect2, varscan2
- SHPK | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV99843602; called by muse, mutect2, varscan2
- SLITRK1 | c.425T>C p.L142S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100999762, COSV65677065; called by muse, mutect2, varscan2
- SOCS6 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV101205633; called by muse, mutect2, varscan2
- SOX17 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99810330; called by muse, mutect2, varscan2
- SYCP1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.934); catalogued as COSV101050721, COSV65694449, COSV65696305; called by muse, mutect2, varscan2
- TAFA2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101352804, COSV69171784; called by muse, mutect2, varscan2
- TAFA4 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs1460960194, COSV99806238; called by muse, mutect2
- THSD4 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1225877683, COSV99964287; called by muse, mutect2, varscan2
- TMEM132A | c.2993G>C p.R998P (on ENST00000453848 / NM_178031.3; = p.R999P on NM_017870.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99133722; called by muse, mutect2, varscan2
- TNFRSF8 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99821051; called by muse, mutect2, varscan2
- TNXB | c.11180T>C p.V3727A (on ENST00000647633; = p.V3480A on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); catalogued as COSV100925738; called by muse, mutect2, varscan2
- TRPC1 | c.172+1G>A p.X58_splice | Splice Site (SNP) | VAF 23/59 reads (39%) | catalogued as COSV99858173; called by muse, mutect2, varscan2
- TTBK1 | c.2401C>T p.Q801* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV52495779, COSV99443605; called by muse, mutect2, varscan2
- TTC16 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100959578; called by muse, mutect2, varscan2
- TTN | c.55692A>G p.I18564M (on ENST00000591111; = p.I11140M on NM_003319.4) | Missense Mutation (SNP) | VAF 33/143 reads (23%) | PolyPhen benign (0.019); catalogued as COSV100592207; called by muse, mutect2, varscan2
- UNC13A | c.4748G>A p.R1583H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs1027624317, COSV53215882; called by muse, mutect2, varscan2
- USP3 | c.1066C>A p.Q356K | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.137); catalogued as COSV99165624; called by muse, mutect2, varscan2
- USP6 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.939); catalogued as COSV100002907; called by muse, mutect2, varscan2
- ZNF503 | c.560A>C p.E187A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV100997975; called by muse, mutect2, varscan2
- ZNF551 | c.1601G>T p.S534I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99989696; called by muse, mutect2, varscan2
- ALOX12 | c.30del p.A12Pfs*52 | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.977del p.N326Tfs*9 | Frame Shift Del (DEL) | VAF 30/134 reads (22%) | called by mutect2, varscan2
- ATRNL1 | c.977A>C p.N326T | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- C3AR1 | c.766del p.S256Lfs*39 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- CD1C | c.535_536dup p.N179Kfs*4 | Frame Shift Ins (INS) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- DNAJC6 | c.167_168del p.V56Dfs*28 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- ESRP2 | c.440del p.K147Rfs*41 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- FUBP1 | c.1558_1576+7del p.X520_splice | Splice Site (DEL) | VAF 14/103 reads (14%) | called by mutect2, pindel
- GK | c.56del p.G19Afs*23 | Frame Shift Del (DEL) | VAF 44/98 reads (45%) | called by mutect2, pindel, varscan2
- ITSN2 | c.339_350delinsC p.S114Wfs*46 | Frame Shift Del (DEL) | VAF 33/166 reads (20%) | called by pindel, varscan2*
- KIAA0232 | c.1892dup p.N631Kfs*9 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- LTBP2 | c.3039del p.E1013Dfs*3 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | called by mutect2, pindel*, varscan2*
- NIPBL | c.1163dup p.N388Kfs*2 | Frame Shift Ins (INS) | VAF 27/120 reads (23%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1289del p.H430Lfs*9 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- PYCR3 | c.739_770del p.A247Hfs*49 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | called by mutect2, pindel
- REM2 | c.628del p.L210Yfs*42 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- SETX | c.3739del p.S1247Qfs*14 | Frame Shift Del (DEL) | VAF 29/144 reads (20%) | called by mutect2, pindel, varscan2
- THOC1 | c.25del p.S9Vfs*17 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.168C>A p.G56= | Silent (SNP) | VAF 71/241 reads (29%) | catalogued as COSV100594486; called by muse, mutect2, varscan2
- BCLAF1 | c.708T>C p.P236= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100786365; called by muse, mutect2, varscan2
- CDK14 | c.804G>T p.G268= (on ENST00000380050 / NM_001287135.2; = p.G250= on NM_012395.3) | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV99723562; called by muse, mutect2
- CNKSR3 | c.105C>T p.I35= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV101527219; called by muse, mutect2, varscan2
- CPSF2 | c.681T>A p.L227= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as COSV100102468; called by muse, mutect2, varscan2
- CRISPLD1 | c.390G>A p.P130= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs369100451; called by muse, mutect2, varscan2
- DLG4 | c.378C>T p.R126= (on ENST00000399506 / NM_001321075.3; = p.R169= on NM_001365.4) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs775658206, COSV57239813; called by muse, mutect2, varscan2
- HOXD4 | c.666A>T p.S222= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100106576; called by muse, mutect2, varscan2
- ITIH5 | c.195C>T p.A65= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV99903577; called by muse, mutect2
- JAK2 | c.2484T>A p.G828= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV101070325; called by muse, mutect2
- L3MBTL1 | c.1038C>T p.F346= (on ENST00000418998 / NM_001377303.1; = p.F256= on NM_015478.7) | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV100916879; called by muse, mutect2, varscan2
- LPIN2 | c.1635C>T p.S545= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV99857891; called by muse, mutect2, varscan2
- LY75 | c.693A>G p.Q231= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV55106587; called by muse, mutect2, varscan2
- MICAL2 | c.1350G>A p.Q450= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs775476180, COSV99816638; called by muse, mutect2, varscan2
- MSANTD1 | c.325T>C p.L109= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV101433554; called by muse, mutect2, varscan2
- PAN2 | c.1245C>T p.N415= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs754140091, COSV99228077; called by muse, mutect2, varscan2
- PCNX1 | c.4779C>G p.L1593= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99453754; called by muse, mutect2, varscan2
- POLR3A | c.3189C>T p.I1063= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100965526; called by muse, mutect2, varscan2
- SCAMP2 | c.63C>A p.P21= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99173913; called by muse, mutect2, varscan2
- SKP2 | c.967C>T p.L323= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99947842; called by muse, varscan2
- SLC10A2 | c.837T>C p.T279= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV99807560; called by muse, mutect2, varscan2
- SLC16A9 | c.345T>C p.L115= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV101264287; called by muse, mutect2, varscan2
- SLC6A15 | c.513G>A p.Q171= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs771090879, COSV99880093; called by muse, mutect2, varscan2
- TTI2 | c.861C>T p.N287= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as COSV100659600; called by muse, mutect2, varscan2
- CPSF6 | c.*3655T>A | 3'UTR (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99878950; called by muse, mutect2, varscan2
- MAP2K4 | c.393+373del | Intron (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- NXT2 | chrX:109535912 G>A | 5'Flank (SNP) | VAF 79/141 reads (56%) | catalogued as COSV99484019; called by muse, mutect2, varscan2
- SH2D6 | n.253A>C | RNA (SNP) | VAF 43/175 reads (25%) | catalogued as COSV100442458; called by muse, mutect2, varscan2
